Somatic mutation profile of tumor specimen C3N-01943-02 (aliquot CPT0163410006) from CPTAC case C3N-01943, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.1 years (23,038 days).
Specimen C3N-01943-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e8ef24f-ece7-4be5-a17f-671a9d807c9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01943-31 (Blood Derived Normal), aliquot CPT0163470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b58b001c-5546-4c16-b478-0373c04b7cef

The open-access MAF lists 156 somatic variants for this specimen: 108 protein-altering or splice-affecting, 24 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 24, Intron 14, Nonsense Mutation 10, RNA 4, Splice Site 3, 5'Flank 2, 3'UTR 2, 3'Flank 1, Frame Shift Ins 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB4 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 28/616 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1562969219; ClinVar: likely pathogenic; called by muse, mutect2
- ABCG4 | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1368207364, COSV56643416; called by muse, mutect2, varscan2
- AOAH | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 116/314 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416939696, COSV99033930; called by muse, mutect2, varscan2
- APC2 | c.1172G>C p.R391P | Missense Mutation (SNP) | VAF 123/603 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs372652826; called by muse, mutect2, varscan2
- ARHGAP29 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs762181862; called by muse, mutect2, varscan2
- BMP8B | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 154/1530 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs777287046; called by muse, varscan2
- C1orf210 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs897432979, COSV70682464; called by muse, mutect2, varscan2
- COPS2 | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM137474, COSV54645795, COSV54646335; called by muse, mutect2, varscan2
- CREBBP | c.5440G>T p.G1814W | Missense Mutation (SNP) | VAF 89/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747252584, COSV52115923, COSV52120627; called by muse, mutect2, varscan2
- DEPP1 | c.580C>G p.R194G | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs199694570; called by muse, mutect2, varscan2
- DOCK2 | c.5086C>T p.R1696W | Missense Mutation (SNP) | VAF 77/443 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs980056604, COSV56944050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELANE | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 94/479 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV52255164; called by muse, mutect2, varscan2
- EML6 | c.1658G>C p.G553A | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs988227191; called by muse, mutect2, varscan2
- FDXR | c.1402C>T p.R468W (on ENST00000293195 / NM_024417.5; = p.R474W on NM_004110.6) | Missense Mutation (SNP) | VAF 58/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1037954215; called by muse, mutect2, varscan2
- FOXG1 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398339; called by muse, mutect2, varscan2
- GABRR1 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs375182799; called by muse, mutect2, varscan2
- GAS6 | c.1249T>C p.Y417H | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs749740507, COSV100582023; called by muse, mutect2, varscan2
- GPR149 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV67666867; called by muse, mutect2
- INPP5F | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.657); catalogued as COSV62822839; called by muse, mutect2, varscan2
- LRRC43 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 83/389 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV60288744; called by muse, mutect2, varscan2
- MFAP3L | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV64372224, COSV64372259; called by muse, mutect2
- MPO | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 132/616 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs756572859; called by muse, mutect2, varscan2
- MSMO1 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs544585398; called by muse, mutect2, varscan2
- MYH4 | c.5692G>T p.A1898S | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs745534450; called by muse, mutect2, varscan2
- NOTCH1 | c.2755G>T p.G919W | Missense Mutation (SNP) | VAF 172/591 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53063387, COSV53078294, COSV99486952; called by muse, mutect2, varscan2
- NRCAM | c.1364G>A p.R455Q (on ENST00000379028 / NM_001371124.1; = p.R449Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs765324546, COSV61031832; called by muse, mutect2, varscan2
- NRK | c.4252G>A p.G1418S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV99687839; called by muse, mutect2, varscan2
- OR9G1 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs772571640, COSV56449306; called by muse, mutect2
- PHB | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs780447025; called by muse, mutect2, varscan2
- PKD1L1 | c.7079C>T p.P2360L | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs982895686, COSV51843093; called by muse, mutect2, varscan2
- POU6F2 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 14/256 reads (5%) | catalogued as COSV68872794; called by muse, mutect2
- PRDM5 | c.29T>A p.F10Y | Missense Mutation (SNP) | VAF 107/534 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV53357993; called by muse, mutect2, varscan2
- RELN | c.9748G>A p.D3250N | Missense Mutation (SNP) | VAF 119/784 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV59002460, COSV59007820; called by muse, mutect2, varscan2
- RIMKLB | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 82/386 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs761192471, COSV55238257; called by muse, mutect2, varscan2
- SVIL | c.6547G>A p.E2183K (on ENST00000355867 / NM_021738.3; = p.E1757K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs758477266, COSV63442718; called by muse, mutect2, varscan2
- TRIM33 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV61820917; called by muse, mutect2
- TRIM6 | c.114C>A p.C38* | Nonsense Mutation (SNP) | VAF 114/511 reads (22%) | catalogued as rs1357945892; called by muse, mutect2, varscan2
- TSHZ2 | c.1715C>A p.T572N | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61587014; called by muse, mutect2, varscan2
- UBTF | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1319419216; called by muse, mutect2, varscan2
- VAMP4 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV52563591; called by muse, mutect2
- WRN | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs772963859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACO1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 41/146 reads (28%) | called by muse, mutect2, varscan2
- AGAP1 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 121/388 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AKNAD1 | c.572A>T p.E191V | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ANK1 | c.2296-1G>A p.X766_splice | Splice Site (SNP) | VAF 27/177 reads (15%) | called by muse, mutect2, varscan2
- BCOR | c.2326C>T p.H776Y | Missense Mutation (SNP) | VAF 157/313 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASQ2 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 70/390 reads (18%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.1445T>A p.I482K | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CCDC18 | c.3774G>C p.K1258N (on ENST00000343253 / NM_001306076.1; = p.K1259N on NM_206886.4) | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CCDC39 | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- CCDC50 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK6 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- CES5A | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CFAP44 | c.2299-2A>G p.X767_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2
- CHD1 | c.2437A>G p.M813V | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNTNAP5 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2
- DPH7 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2
- DSC2 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- EEF2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 50/735 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- ERBB2 | c.2596C>A p.L866M | Missense Mutation (SNP) | VAF 71/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN3 | c.2792C>A p.P931H | Missense Mutation (SNP) | VAF 115/577 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- FMN2 | c.4664G>T p.C1555F | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- GPS2 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 62/252 reads (25%) | called by muse, mutect2
- GRIK3 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPCL2 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HS3ST2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 87/468 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGKV6D-21 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.013); called by muse, mutect2
- KCNH3 | c.3134dup p.P1046Tfs*62 | Frame Shift Ins (INS) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- KLF7 | c.418T>C p.S140P | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2
- KLHL33 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- KRTAP4-6 | c.490T>C p.C164R | Missense Mutation (SNP) | VAF 146/1568 reads (9%) | SIFT deleterious (0.02); called by muse, mutect2
- MAP7D1 | c.1592G>C p.R531P | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MFSD2A | c.418G>T p.V140F (on ENST00000372809 / NM_001136493.3; = p.V127F on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MSRB2 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NDUFB2 | c.149T>A p.L50Q | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NPHP3 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); called by muse, mutect2
- NR5A1 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- OR2T11 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 104/208 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T2 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 175/524 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, varscan2
- PCLO | c.7964C>A p.A2655E | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PHYKPL | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 65/354 reads (18%) | called by muse, mutect2, varscan2
- PLEC | c.5878G>A p.D1960N (on ENST00000322810 / NM_201380.4; = p.D1850N on NM_000445.5) | Missense Mutation (SNP) | VAF 90/675 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PML | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRORP | c.1406_1407insA p.C469* | Nonsense Mutation (INS) | VAF 78/246 reads (32%) | called by mutect2, varscan2
- PSME4 | c.2721C>A p.H907Q | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PTPN13 | c.2429G>C p.G810A | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRF | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM46 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RFX4 | c.1612T>A p.Y538N (on ENST00000392842 / NM_213594.3; = p.Y444N on NM_032491.6) | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RINL | c.50+1G>T p.X17_splice | Splice Site (SNP) | VAF 52/302 reads (17%) | called by muse, mutect2, varscan2
- SCLT1 | c.1752A>C p.Q584H | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SHANK1 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 63/336 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- SHROOM1 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC43A3 | c.285C>G p.F95L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.392); called by muse, mutect2
- SMAD7 | c.42G>C p.W14C | Missense Mutation (SNP) | VAF 175/440 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SMPD1 | c.1787G>A p.C596Y | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRCAP | c.7864C>T p.Q2622* | Nonsense Mutation (SNP) | VAF 52/247 reads (21%) | called by muse, mutect2, varscan2
- TIGD7 | c.729T>A p.S243R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TPH2 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 77/396 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRAPPC3L | c.31T>C p.Y11H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TRIM64B | c.752C>A p.S251* | Nonsense Mutation (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- TRMT61B | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UMODL1 | c.869G>A p.W290* | Nonsense Mutation (SNP) | VAF 73/375 reads (19%) | called by muse, mutect2, varscan2
- ZNF256 | c.1532G>C p.R511T | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ZNF329 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, varscan2
- ZNF444 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF664 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ZNF804B | c.2591A>C p.Y864S | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ACSL6 | c.891C>T p.F297= (on ENST00000379240; = p.F322= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/262 reads (18%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.4944G>A p.P1648= | Silent (SNP) | VAF 90/288 reads (31%) | catalogued as rs138611846; called by muse, mutect2, varscan2
- BAX | c.399C>T p.I133= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as rs1249224639, COSV53172090; called by muse, varscan2
- BMP1 | c.1944C>T p.F648= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs766899712, COSV60479378; called by muse, mutect2, varscan2
- C1QTNF4 | c.522G>A p.E174= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- COL6A2 | c.1401C>T p.D467= | Silent (SNP) | VAF 131/600 reads (22%) | called by muse, mutect2, varscan2
- ETFB | c.561C>G p.L187= | Silent (SNP) | VAF 83/525 reads (16%) | catalogued as rs1446696536; called by muse, mutect2, varscan2
- EXT2 | c.1542T>G p.T514= (on ENST00000343631; = p.T547= on NM_000401.3) | Silent (SNP) | VAF 41/188 reads (22%) | called by muse, mutect2, varscan2
- GPR142 | c.675G>A p.Q225= | Silent (SNP) | VAF 107/486 reads (22%) | catalogued as COSV59520468; called by muse, mutect2, varscan2
- HUNK | c.1221G>A p.Q407= | Silent (SNP) | VAF 54/298 reads (18%) | called by muse, mutect2, varscan2
- IGFN1 | c.2262G>A p.S754= (on ENST00000295591 / NM_001367841.1; = p.S3211= on NM_001164586.2) | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as rs373760324; called by muse, mutect2, varscan2
- KIF16B | c.1335T>C p.I445= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- NLRP4 | c.1356C>T p.H452= | Silent (SNP) | VAF 107/307 reads (35%) | catalogued as rs748009448, COSV56712645; called by muse, mutect2, varscan2
- NRXN1 | c.306G>C p.T102= | Silent (SNP) | VAF 38/211 reads (18%) | catalogued as COSV101277057, COSV101280827; called by muse, mutect2, varscan2
- PCDHA4 | c.897T>C p.T299= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs371031734; called by muse, mutect2, varscan2
- POLR1A | c.3447C>G p.V1149= | Silent (SNP) | VAF 131/586 reads (22%) | called by muse, mutect2, varscan2
- PRDM5 | c.30C>T p.F10= | Silent (SNP) | VAF 106/536 reads (20%) | called by muse, mutect2, varscan2
- SERPINA4 | c.315G>T p.L105= | Silent (SNP) | VAF 243/631 reads (39%) | catalogued as rs934976944; called by muse, mutect2, varscan2
- TECPR1 | c.1422G>T p.T474= | Silent (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- USP4 | c.2574G>T p.L858= | Silent (SNP) | VAF 35/200 reads (18%) | called by muse, mutect2, varscan2
- YIF1B | c.570G>A p.A190= (on ENST00000339413 / NM_001039673.3; = p.A175= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/333 reads (23%) | catalogued as rs200933266, COSV56651470; called by muse, mutect2, varscan2
- ZBTB38 | c.1623C>T p.I541= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs749495655, COSV58544187; called by muse, mutect2, varscan2
- ZNF215 | c.255G>A p.K85= | Silent (SNP) | VAF 40/200 reads (20%) | called by muse, mutect2, varscan2
- ZNF682 | c.1138A>C p.R380= | Silent (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.4656+30G>T | Intron (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2
- AOPEP | c.1978-12C>G | Intron (SNP) | VAF 14/50 reads (28%) | called by muse, varscan2
- CIT | c.3714+43C>T | Intron (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- COPB2 | c.3+39G>C | Intron (SNP) | VAF 17/124 reads (14%) | called by mutect2, varscan2
- CSNK1E | c.885+632A>G | Intron (SNP) | VAF 51/173 reads (29%) | called by muse, mutect2, varscan2
- FOLH1 | c.119-643C>G | Intron (SNP) | VAF 42/193 reads (22%) | catalogued as rs950159929; called by muse, mutect2, varscan2
- GH2 | c.457-40C>T | Intron (SNP) | VAF 110/498 reads (22%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+972C>T | Intron (SNP) | VAF 13/424 reads (3%) | catalogued as rs1568877050; called by muse, mutect2
- IGLV7-46 | c.-23G>A | 5'UTR (SNP) | VAF 64/274 reads (23%) | called by muse, mutect2, varscan2
- IGSF9B | c.64+4651T>A | Intron (SNP) | VAF 43/168 reads (26%) | called by muse, mutect2, varscan2
- LGMN | c.*253G>C | 3'UTR (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- LINC00917 | n.1437C>T | RNA (SNP) | VAF 106/631 reads (17%) | catalogued as rs759082238; called by muse, mutect2, varscan2
- NAP1L4 | c.*98C>G | 3'UTR (SNP) | VAF 12/167 reads (7%) | catalogued as rs913008775; called by muse, mutect2
- OR6W1P | n.652C>G | RNA (SNP) | VAF 58/352 reads (16%) | called by muse, mutect2, varscan2
- OR6W1P | n.547C>G | RNA (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- PCDHB6 | chr5:141157115 del C | 3'Flank (DEL) | VAF 35/202 reads (17%) | called by mutect2, pindel, varscan2
- PDHX | c.965-319A>G | Intron (SNP) | VAF 28/163 reads (17%) | catalogued as rs117341628; called by muse, mutect2, varscan2
- PRRC1 | c.1128+114_1128+117del | Intron (DEL) | VAF 15/64 reads (23%) | catalogued as rs752655024; called by mutect2, pindel, varscan2
- RUNX1 | c.724+165G>A | Intron (SNP) | VAF 10/265 reads (4%) | called by muse, mutect2
- SEC61A2 | c.463-1985G>C | Intron (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- SNORD114-19 | n.18T>A | RNA (SNP) | VAF 64/157 reads (41%) | called by muse, mutect2, varscan2
- SYT17 | c.1229-16914C>A | Intron (SNP) | VAF 38/212 reads (18%) | catalogued as rs1354968730; called by muse, mutect2, varscan2
- TIGIT | chr3:114293960 G>T | 5'Flank (SNP) | VAF 81/307 reads (26%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439919 G>A | 5'Flank (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
